RC case RC-B6SM — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Lymph nodes. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dad37f92-3974-4fd1-9104-cdd5826e6a8e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1932; Vital status: Dead; Days to death: 1,110 days (3.0 years); Year of death: 2013; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (2)
1. Angioimmunoblastic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9705/3; ICD-10 code: C84; Tissue or organ of origin: Lymph nodes of axilla or arm; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: primary; Age at diagnosis: 78.2 years (28,564 days); Year of diagnosis: 2010; Method of diagnosis: Excisional Biopsy; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann arbor b symptoms described array: Fever / Weight Loss / Night Sweats; Ann Arbor extranodal involvement: No; International Prognostic Index (IPI): Low Risk; Sites of involvement: Lymph Node, Axillary.
   Pathology details: Bone marrow malignant cells: Yes; Greatest tumor dimension: 2.9 cm; Timepoint category: Initial Diagnosis.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Recurrence (histology not recorded by GDC). Age at diagnosis: 80.0 years (29,205 days); Days to diagnosis: 641 days (1.8 years).

Follow-up (4 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 80.
- Days to follow up: 5 days; Disease response: With Tumor.
- Day 641 (recurrence): Progression or recurrence: Yes; Days to recurrence: 641 days (1.8 years).
- Follow-up contact recording only the day: day 1,110.

Molecular and laboratory tests
- Lactate Dehydrogenase 345 U/L [Blood test normal range upper: 250].
- Epstein-Barr Virus (ISH): Negative.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Skin Rash.
- Timepoint category: Prior to Diagnosis; Comorbidities: Acute Renal Failure.
- Timepoint category: Initial Diagnosis; Weight: 54 kg; Height: 150 cm; BMI: 24.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Pancreas Cancer.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B6SM-NB1-A: Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample RC-B6SM-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide RC-B6SM-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 75; Percent normal cells: 15; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 3.
